Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAKO, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAKO-01A (Primary Tumor).

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 5.0 cm; no angio-invasion; no invasion of rete testis; no invasion of tunica albuginea; epididymis and spermatic cord not present in the available slides.

Testistumor left (at the same time): seminoma, see

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
3/5/14

Source: NCI Genomic Data Commons file 12415b7d-fb8b-43d0-b2a5-10096e31df2b (TCGA-2G-AAKO.DEF8C924-E3D1-4C7C-A94B-79ED892A4E98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).